Gene-level copy-number profile of tumor specimen HTMCP-02-01-01249-01A from CGCI case HTMCP-02-01-01249, project CGCI-HTMCP-LC (HIV+ Tumor Molecular Characterization Project - Lung Cancer). Sex at birth: male.
Specimen HTMCP-02-01-01249-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file ee81e8f3-82ea-48cf-b59e-eee7c7be80e7.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-02-01-01249-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,714 have no estimate.
https://portal.gdc.cancer.gov/files/8e2ad9d0-3491-4647-b609-23ceba6907e0

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 206; copy number 1: 16,401; copy number 2: 26,963; copy number 3: 13,028; copy number 4: 1,895; copy number 5: 217; copy number 6: 2; copy number 7: 87; copy number 10: 23; copy number 13: 62; copy number 17: 4; copy number 20: 1; copy number 23: 1; copy number 24: 3; copy number 35: 6; copy number 40: 10.

Homozygous deletions (total copy number 0; autosomes only): 193 genes in 19 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:81,306,147–81,992,436, 9 genes: ADGRL2, HNRNPA3P14, ARID3BP1, AL138799.1, AL138799.3, MED28P8, AC117944.1, AL138799.2, ST13P20.
- chr3:28,349,178–29,767,537, 1 gene (within-gene range 0–1): AC098650.1.
- chr3:28,574,791–30,010,391, 2 genes (within-gene range 0–1): RBMS3, RBMS3-AS3.
- chr3:29,390,848–29,934,156, 4 genes: RPS12P5, RBMS3-AS2, MTND4LP9, RBMS3-AS1.
- chr3:49,940,007–50,596,168, 35 genes: RBM6, RBM5, RBM5-AS1, SEMA3F-AS1, SEMA3F, AC104450.1, GNAT1, SLC38A3, GNAI2, MIR5787, U73169.1, U73166.1, SEMA3B-AS1, SEMA3B, MIR6872, LSMEM2, IFRD2, HYAL3, NAA80, HYAL1, HYAL2, TUSC2, RASSF1, RASSF1-AS1, ZMYND10-AS1, ZMYND10, NPRL2, CYB561D2, Z84492.2, TMEM115, CACNA2D2, Z84492.1, RNA5SP131, C3orf18, HEMK1.
- chr3:64,092,236–66,038,834, 19 genes (within-gene range 0–2): PRICKLE2, PRICKLE2-AS1, PRICKLE2-AS2, PRDX3P4, PRICKLE2-AS3, PRICKLE2-DT, RNU6-739P, ADAMTS9, ADAMTS9-AS1, ADAMTS9-AS2, LINC02040, MAGI1, AC121493.1, ILF2P1, RPL17P17, MAGI1-IT1, MAGI1-AS1, Y_RNA, AC106827.1.
- chr4:6,269,849–6,308,636, 2 genes: WFS1, AC116317.1.
- chr5:52,673,186–52,990,278, 7 genes (within-gene range 0–1): AC022126.1, PELO, ITGA1, AC022133.2, B3GNTL1P1, AC022133.1, AC025180.1.
- chr8:30,382,119–30,658,236, 5 genes (within-gene range 0–2): RBPMS-AS1, RBPMS, AC102945.2, GTF2E2, AC102945.1.
- chr9:21,077,104–25,089,151, 70 genes (broad region; genes not listed).
- chr9:40,755,407–40,883,763, 4 genes: AL353626.3, RNU6-156P, AL353626.1, AL353626.2.
- chr10:46,233,885–46,273,557, 1 gene: ANTXRLP1.
- chr10:59,246,130–59,364,075, 3 genes (within-gene range 0–1): FAM13C, AC025038.1, AL355474.1.
- chr10:119,207,571–119,459,745, 5 genes (within-gene range 0–1): GRK5, GRK5-IT1, RN7SL749P, AL583824.1, MIR4681.
- chr11:55,635,113–55,666,195, 3 genes: OR4P4, OR4S2, OR4C6.
- chr11:113,974,881–114,256,765, 3 genes (within-gene range 0–1): HTR3A, ZBTB16, AP002755.1.
- chr15:57,319,138–57,782,762, 12 genes: LINC01413, NDUFB10P1, CGNL1, RNU6-844P, AC025271.3, AC025271.2, AC025271.4, AC025271.1, MYZAP, GCOM1, POLR2M, AC090651.1.
- chr15:57,979,716–57,990,636, 2 genes (within-gene range 0–1): AC012653.1, AC012653.2.
- chr15:77,100,656–77,534,110, 6 genes: PEAK1, AC087465.1, AC060773.1, HMG20A, AC090984.1, AC046168.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 389 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:100,572,889–101,452,452, 32 genes, copy number 5: SNX31, AP001205.1, RNU6-1092P, PABPC1, MIR7705, RNU6ATAC41P, Y_RNA, RPS20P23, RNU4-83P, RPS26P6, Metazoa_SRP, AC027373.1, YWHAZ, RN7SL685P, FLJ42969, AP003469.2, AP003469.1, RN7SKP249, AP003469.3, ZNNT1, ZNF706, AP001330.4, AP001330.2, LINC02844, AP001330.1, RNU7-67P, AP001330.3, NACA4P, DUXAP2, LINC02845, RN7SL563P, AP001208.1.
- chr9:25,676,389–28,670,286, 33 genes, copy number 7–13 (within-gene range 3–13): TUSC1, LINC01241, FAM71BP1, AL353753.1, AL442639.1, AL451137.2, AL451137.1, AL356133.1, CAAP1, H3P31, RN7SL100P, PLAA, IFT74, IFT74-AS1, LRRC19, AL355432.1, TEK, RNA5SP280, AL355433.1, LINC00032, EQTN, MOB3B, AL163192.1, AL451123.2, IFNK, AL451123.1, C9orf72, CTAGE12P, AL360014.1, AL353746.1, LINGO2, AL451124.1, AL445526.1.
- chr9:38,620,474–40,642,117, 51 genes, copy number 5 (within-gene range 4–5): FAM201A, YWHABP1, RNU6-765P, AL845311.1, VN2R3P, CNTNAP3, RBM17P1, AL353729.2, AL353729.1, RN7SL640P, SPATA31A1, BX005214.3, FAM74A1, BX005214.1, BX005214.2, ZNF658B, SKP1P3, FKBP4P2, SDR42E1P1, ATP5F1AP8, RAB28P1, RBPJP5, GLIDR, BX664615.1, FGF7P3, BX664615.2, RN7SL763P, SNORA70, CR769767.1, AL772307.1, RPL7AP49, AL773545.3, CDRT15P14, AL773545.1, AL773545.2, ANKRD20A2P, BX664727.3, RNU6-1269P, BX664727.2, SNX18P8, FAM95B1, BX664727.1, CNN2P2, GXYLT1P3, AL591471.1, AQP7P5, FP885919.1, AMYH02020865.1, BMS1P14, FP325318.1, IGKV1OR9-2.
- chr11:54,591,480–54,725,816, 11 genes, copy number 7: OR4C50P, OR4C46, OR4C7P, OR4R2P, OR4A4P, OR4A3P, OR4A2P, OR4A8, OR4A7P, OR4A5, OR4A6P.
- chr11:55,723,776–56,418,232, 57 genes, copy number 5: OR5D3P, OR5D17P, OR5D13, OR5D15P, OR5D14, OR5L1, OR5D18, OR5L2, OR5D16, OR9M1P, AC036111.2, AC036111.3, AC036111.1, TRIM51, OR5W1P, OR5W2, OR5I1, OR10AF1P, OR10AK1P, OR10AG1, OR7E5P, OR5F1, OR5F2P, OR5AS1, OR5AQ1P, OR5J1P, OR5BE1P, OR8I2, OR8I4P, OR8H2, OR5BN2P, OR8H3, OR5BN1P, OR8J3, OR8K4P, OR8K5, OR5J7P, OR5J2, OR8V1P, AC022882.1, OR8J2, OR5T2, OR5T3, OR5T1, OR8H1, OR8I1P, OR8K3, FAM8A2P, OR8K2P, OR8K1, OR8J1, RPL5P29, OR8U1, OR8L1P, OR5AL2P, OR5AL1, OR5R1.
- chr11:66,744,451–66,843,516, 1 gene, copy number 13 (within-gene range 3–13): C11orf80.
- chr11:66,842,835–68,213,828, 78 genes, copy number 7–13 (broad region; genes not listed).
- chr11:69,641,156–71,608,040, 53 genes, copy number 5–10: CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN, SHANK2, AP001271.1, AP001271.2, SHANK2-AS1, SHANK2-AS2, Y_RNA, AP000590.1, SHANK2-AS3, MIR3664, AP003783.1, ACTE1P, DHCR7, AP002387.1, NADSYN1, MIR6754, AP000867.2, KRTAP5-7, KRTAP5-8, KRTAP5-9, AP000867.5, KRTAP5-10, AP000867.1, KRTAP5-11, KRTAP5-14P, OR7E87P, UNC93B6.
- chr11:73,400,487–73,598,189, 1 gene, copy number 5 (within-gene range 1–5): FAM168A.
- chr11:73,510,658–74,254,703, 24 genes, copy number 5 (within-gene range 1–5): AP000763.2, HMGN2P38, AP000860.1, PLEKHB1, RAB6A, AP002993.1, AP002770.1, MRPL48, RN7SKP243, CCDC58P5, COA4, PAAF1, ARPC3P4, DNAJB13, AP003717.1, UCP2, AP003717.2, AP003717.3, UCP3, C2CD3, AP002392.1, PPME1, RNA5SP343, AP000577.2.
- chr13:38,902,387–38,936,199, 2 genes, copy number 5: PLA2G12AP2, ANKRD26P2.
- chr13:73,191,528–73,661,891, 6 genes, copy number 5: RNU4-10P, RNY1P8, AL162376.1, MARK2P12, LINC00393, LINC00392.
- chr20:9,505,180–11,345,855, 33 genes, copy number 5: LAMP5-AS1, LAMP5, PAK5, AL353612.2, AL353612.1, AL034427.1, PARAL1, ANKEF1, SNAP25-AS1, Metazoa_SRP, AL354824.1, AL354824.2, SNAP25, AL023913.1, HIGD1AP15, RPL23AP6, SDAD1P2, MKKS, AL034430.1, AL034430.2, SLX4IP, AL035456.1, JAG1, MIR6870, AL050403.2, LINC01752, AL135937.1, AL050403.1, FAT1P1, LINC02871, AL158042.1, AL049649.1, RPS11P1.
- chr20:20,363,691–20,370,949, 2 genes, copy number 6: AL161658.1, INSM1.
- chr20:47,950,797–48,074,188, 5 genes, copy number 5: AL357558.2, AL357558.1, LINC01522, LINC01523, AL139351.1.

Autosomal genes at a single copy (total copy number 1): 13,775. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
